Gene-level copy-number profile of tumor specimen TCGA-EB-A82C-01A from TCGA case TCGA-EB-A82C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.8 years (25,863 days).
Specimen TCGA-EB-A82C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.b771c8a5-c7d9-43e3-b0a5-0dbb0ffe2d83.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A82C-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2b02ec5b-8e2c-44ab-ad4d-2a4f3e18c2d7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 546; copy number 2: 18,519; copy number 3: 20,019; copy number 4: 14,924; copy number 5: 3,743; copy number 6: 1,717; copy number 7: 52; copy number 8: 112; copy number 9: 13; copy number 10: 77; copy number 11: 4; copy number 15: 12; copy number 20: 26; copy number 26: 12; copy number 29: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A82C-01A-11D-A34T-01): tumor purity 0.84, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–22,214,672, 7 genes: CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 333 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,974,356–35,557,950, 18 genes, copy number 10 (within-gene range 2–10): AC114490.3, AC114490.1, AC114490.2, TMEM35B, ZMYM6, ZMYM1, RPL12P45, EFCAB14P1, AL590434.1, SFPQ, Y_RNA, ZMYM4, RN7SL503P, SNORA62, RPL5P4, ZMYM4-AS1, Metazoa_SRP, KIAA0319L.
- chr1:38,129,464–38,859,772, 10 genes, copy number 8 (within-gene range 3–8): LINC02786, AL390839.1, AL390839.2, LINC01343, AL513479.1, RNU6-753P, LINC01685, HSPA5P1, AL354702.1, RRAGC.
- chr1:45,510,914–46,941,484, 51 genes, copy number 8 (within-gene range 5–8): PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8, CYP4A11.
- chr1:49,994,318–50,203,772, 4 genes, copy number 11 (within-gene range 5–11): AL645730.1, MTND2P29, ELAVL4, AL583843.1.
- chr1:50,405,430–50,425,316, 3 genes, copy number 8: FCF1P6, DMRTA2, AL049637.1.
- chr1:50,461,469–50,471,150, 1 gene, copy number 8: FAF1-AS1.
- chr1:61,588,049–61,742,424, 4 genes, copy number 9: AC099791.4, AC099791.1, TM2D1, AC099791.2.
- chr1:64,384,398–64,693,058, 3 genes, copy number 9: RNU7-62P, CACHD1, MIR4794.
- chr1:76,074,746–76,634,603, 1 gene, copy number 7 (within-gene range 4–10): ST6GALNAC3.
- chr1:76,636,877–76,637,339, 1 gene, copy number 7: AC104458.1.
- chr1:90,242,088–90,855,253, 10 genes, copy number 10: AC098656.1, RNU6-695P, AL627316.1, LINC02787, SNORD3G, BARHL2, AC092805.1, LINC02609, LINC02788, LINC01763.
- chr1:95,510,059–95,782,342, 1 gene, copy number 9 (within-gene range 4–10): LINC02607.
- chr1:96,583,209–96,696,167, 4 genes, copy number 10: RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270.
- chr1:97,095,923–97,322,955, 1 gene, copy number 9 (within-gene range 5–9): DPYD-AS1.
- chr1:99,646,113–103,927,806, 75 genes, copy number 7–10 (broad region; genes not listed).
- chr1:108,134,043–108,433,184, 9 genes, copy number 7 (within-gene range 2–7): SLC25A24, AL359258.2, AL359258.3, NBPF4, AL359258.1, SLC25A24P1, NBPF5P, SLC25A24P2, AL390038.1.
- chr5:107,859,035–109,885,423, 25 genes, copy number 29 (within-gene range 2–34): FBXL17, AC008462.1, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1.
- chr9:22,446,824–22,824,213, 2 genes, copy number 9: DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes, copy number 9: CLIC4P1, AC017067.1.
- chr9:110,190,048–112,890,876, 50 genes, copy number 15–26: C9orf152, TXN, TXNDC8, SVEP1, RNU6-1039P, AL592463.1, MUSK, AL513328.1, LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668, RNU6-710P, AL138756.1, SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2, C9orf147, KIAA1958, AL445187.1, INIP, AL390067.1, SNX30, SLC46A2, AL139041.1.
- chr9:112,959,134–112,962,261, 1 gene, copy number 7 (within-gene range 5–7): MUPP.
- chr17:28,662,198–29,340,822, 47 genes, copy number 8: SUPT6H, AC010761.3, PROCA1, RAB34, RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35.
- chr20:15,552,157–16,670,742, 10 genes, copy number 7–10: AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 546. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
